TCGA case TCGA-RP-A690 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c7ecf63a-a412-43e6-805e-e9f49d7dfe6b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; ICD-10 code: C72.0; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Spinal cord; Classification of tumor: metastasis; Age at diagnosis: 66.9 years (24,450 days); Year of diagnosis: 2005; AJCC staging edition: 6th; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 6 days; Melanoma known primary: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.

Follow-up (1 entry)
- Days to follow up: 6 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 49 kg; Height: 162 cm; BMI: 18.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RP-A690-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RP-A690-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-RP-A690-06A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-RP-A690-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Primary location: Distant Metastasis; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas, Site: Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 6 days; disease-specific survival: no event (censored), 6 days; progression-free interval: no event (censored), 6 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RP-A690-06A-11D-A30W-01): tumor purity 0.96, ploidy 2.02, whole-genome doublings 0.
